Somatic mutation profile of tumor specimen TCGA-DU-6402-01A (aliquot TCGA-DU-6402-01A-11D-1705-08) from TCGA case TCGA-DU-6402, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 52.6 years (19,207 days).
Specimen TCGA-DU-6402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73f857d3-6af0-4434-80ea-6c6d7237ee8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6402-10A (Blood Derived Normal), aliquot TCGA-DU-6402-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af74b7ae-d189-4c68-b9b9-6304ccc232eb

The open-access MAF lists 44 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 13, Frame Shift Del 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs57374291, CM1111458, CM131884, COSV64291957, COSV64294035, COSV64296475; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- B3GNT7 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771622315, COSV55006899; called by muse, mutect2, varscan2
- CD70 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs148772362; called by muse, mutect2, varscan2
- CLHC1 | c.1525G>C p.G509R | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV68464397; called by muse, mutect2, varscan2
- COBLL1 | c.1046C>A p.A349E (on ENST00000392717; = p.A311E on NM_014900.5) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV52070927; called by muse, mutect2, varscan2
- DAPK1 | c.2319G>A p.M773I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1021325129, COSV63789000; called by muse, mutect2, varscan2
- DDC | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs371272735; called by muse, mutect2, varscan2
- EXPH5 | c.4549C>A p.L1517I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV56204580; called by muse, mutect2, varscan2
- EXPH5 | c.3701C>G p.T1234R | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV56203064, COSV56204596, COSV56204646; called by muse, mutect2, varscan2
- FZD10 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459615151, COSV57474404; called by muse, mutect2, varscan2
- GRM3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64472446, COSV64474804; called by muse, mutect2, varscan2
- IGHD | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV101162907; called by muse, mutect2, varscan2
- KCNS3 | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.996); catalogued as COSV58407828; called by muse, mutect2, varscan2
- LRRC3 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774890658, COSV52399282; called by muse, mutect2, varscan2
- MARCHF11 | c.1132A>G p.N378D | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV60130968; called by muse, mutect2, varscan2
- MYO15A | c.7267G>A p.G2423S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs530783345, COSV52755692, COSV52756702; called by muse, mutect2, varscan2
- NEDD4L | c.1214A>G p.N405S (on ENST00000400345 / NM_001144967.3; = p.N385S on NM_015277.6) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1330224857, COSV56847837; called by muse, mutect2, varscan2
- NF1 | c.1675del p.D559Ifs*9 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as COSV62211191; called by mutect2, pindel, varscan2
- NF1 | c.6242T>G p.L2081* (on ENST00000358273 / NM_001042492.3; = p.L2060* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV62209224; called by muse, mutect2, varscan2
- PLOD1 | c.2078G>T p.R693M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52146661; called by muse, mutect2
- PPEF2 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV54423885; called by muse, mutect2, varscan2
- PRAMEF4 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs775644555, COSV52439564; called by muse, mutect2, varscan2
- PROM1 | c.2009T>C p.L670P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71699628; called by muse, mutect2, varscan2
- RYR2 | c.5235A>T p.K1745N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as COSV63695685, COSV63711004; called by muse, varscan2
- SFI1 | c.3454G>C p.E1152Q (on ENST00000400288 / NM_001007467.3; = p.E1121Q on NM_014775.4) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56717894; called by muse, mutect2, varscan2
- SLC26A3 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758633508, COSV60639959; called by muse, mutect2, varscan2
- TCHH | c.3308G>A p.R1103H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs767039175, COSV64275966; called by muse, mutect2, varscan2
- TICRR | c.3883C>A p.P1295T | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV51543338; called by muse, mutect2, varscan2
- UBE2M | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53397279; called by muse, mutect2, varscan2
- CCKAR | c.1080C>T p.Y360= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as rs150897748; called by muse, mutect2, varscan2
- FAT4 | c.1593C>T p.L531= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs745357271, COSV67891589; called by muse, mutect2, varscan2
- FSCB | c.1467C>T p.A489= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs748894618, COSV61217195; called by muse, mutect2, varscan2
- MS4A6E | c.381T>A p.S127= | Silent (SNP) | VAF 74/265 reads (28%) | catalogued as COSV55727466; called by muse, mutect2, varscan2
- PCDHA2 | c.1521C>T p.Y507= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV65365677; called by muse, mutect2, varscan2
- PCDHB2 | c.1506C>T p.L502= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as rs1554271463, COSV50564243; called by muse, mutect2, varscan2
- PDIA6 | c.738C>T p.G246= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs779374855, COSV55350090; called by muse, mutect2, varscan2
- PHACTR3 | c.951G>A p.G317= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV63030483; called by muse, mutect2, varscan2
- PKHD1 | c.5499G>A p.S1833= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as rs557919334, COSV61884065; called by muse, mutect2, varscan2
- RPL10L | c.537C>T p.D179= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs770334898, COSV53560511; called by muse, mutect2, varscan2
- SDK2 | c.2397C>T p.H799= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs1053433876, COSV66190319; called by muse, mutect2, varscan2
- SPHKAP | c.345C>T p.I115= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as COSV60884816; called by muse, mutect2
- UGT2B17 | c.33G>A p.L11= | Silent (SNP) | VAF 52/371 reads (14%) | catalogued as COSV58502047; called by muse, mutect2, varscan2
- DEPDC5 | c.*837C>T | 3'UTR (SNP) | VAF 13/45 reads (29%) | catalogued as rs1223453056, COSV56702513; called by muse, mutect2, varscan2
